Somatic mutation profile of tumor specimen TCGA-K7-A5RF-01A (aliquot TCGA-K7-A5RF-01A-11D-A28X-10) from TCGA case TCGA-K7-A5RF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 64.5 years (23,557 days).
Specimen TCGA-K7-A5RF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3422d35e-fc5d-4175-b345-217f75e9cf20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K7-A5RF-10B (Blood Derived Normal), aliquot TCGA-K7-A5RF-10B-01D-A28X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdef0d05-1530-483e-ade8-f281670e5e8f

The open-access MAF lists 60 somatic variants for this specimen: 41 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 18, Nonsense Mutation 2, Frame Shift Del 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1BG | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54052781; called by muse, mutect2, varscan2
- AC004593.2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56098791, COSV56101160; called by muse, mutect2
- ACSL3 | c.1345T>G p.L449V | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV100658005; called by muse, mutect2
- AP2M1 | c.444G>T p.Q148H | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV53049658; called by muse, mutect2
- ATP11C | c.1139A>T p.D380V | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59570502; called by muse, mutect2, varscan2
- ATP1A3 | c.1070A>T p.K357M (on ENST00000545399 / NM_001256214.2; = p.K344M on NM_152296.5) | Missense Mutation (SNP) | VAF 19/295 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57490157; called by muse, mutect2
- BTAF1 | c.2537A>G p.N846S | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56437674; called by muse, mutect2
- CASP6 | c.438C>G p.D146E | Missense Mutation (SNP) | VAF 16/273 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as COSV54461635; called by muse, mutect2
- CORIN | c.1702C>A p.Q568K | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV56696761; called by muse, mutect2
- CSMD1 | c.4712T>C p.I1571T (on ENST00000520002; = p.I1570T on NM_033225.6) | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV59363612; called by muse, mutect2
- CYP3A5 | c.101A>G p.K34R | Missense Mutation (SNP) | VAF 28/271 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV56122014; called by muse, mutect2
- DCAF12L2 | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 25/168 reads (15%) | catalogued as COSV63582223, COSV63583649; called by muse, mutect2, varscan2
- EIF3B | c.1339A>C p.S447R | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV62804392; called by muse, mutect2, varscan2
- ENTHD1 | c.831A>G p.A277= | Splice Region (SNP) | VAF 7/73 reads (10%) | catalogued as COSV57323642; called by muse, mutect2, varscan2
- FGR | c.275C>A p.T92N | Missense Mutation (SNP) | VAF 17/318 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.505); catalogued as COSV64969692; called by muse, mutect2
- GPR22 | c.1222C>A p.P408T | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.992); catalogued as rs1289051978, COSV51760225; called by muse, mutect2
- IL6 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV51733778; called by muse, mutect2
- IQGAP2 | c.919G>T p.V307L | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.638); catalogued as COSV57179019; called by muse, mutect2
- KDM5D | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV58737023; called by muse, mutect2
- KLB | c.1814C>T p.S605L | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1236022642, COSV57303941; called by muse, mutect2
- KRT73 | c.1107G>T p.K369N | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59841104; called by muse, mutect2
- KRTAP5-2 | c.146G>A p.C49Y | Missense Mutation (SNP) | VAF 14/159 reads (9%) | PolyPhen benign (0.011); catalogued as COSV69015224; called by muse, mutect2
- MACC1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.052); catalogued as COSV60545326; called by muse, mutect2
- MSH3 | c.1939C>G p.H647D | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.416); catalogued as COSV54159706; called by muse, mutect2
- P2RY4 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65737020; called by muse, mutect2, varscan2
- RNF20 | c.563T>C p.I188T | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV66355834; called by muse, mutect2
- RUNX1T1 | c.301C>T p.P101S (on ENST00000265814 / NM_001198628.1; = p.P74S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56155767; called by muse, mutect2
- SCRIB | c.1764G>T p.Q588H | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100254597, COSV57591693; called by muse, mutect2
- SEC22C | c.11T>G p.I4S | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52566607; called by muse, mutect2
- SLAMF1 | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52498649, COSV52500282; called by muse, mutect2
- SRGAP2 | c.3088G>T p.A1030S (on ENST00000624873 / NM_001170637.4; = p.A1031S on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/396 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.146); catalogued as COSV55341473; called by muse, mutect2
- SYNE3 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.275); catalogued as rs201231576, COSV62080650, COSV62081507; called by muse, mutect2
- SYT3 | c.1396T>C p.F466L | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.291); catalogued as rs1411577834, COSV58898348; called by muse, mutect2
- UNC5D | c.2131T>C p.Y711H | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV54821789; called by muse, mutect2
- USP5 | c.2491A>T p.I831F (on ENST00000229268 / NM_001098536.2; = p.I808F on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/158 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99978839; called by muse, mutect2
- WNK4 | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55908682; called by muse, mutect2
- YIF1B | c.813C>G p.I271M (on ENST00000339413 / NM_001039673.3; = p.I256M on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs979109170, COSV56651460; called by muse, mutect2
- ZC3H11A | c.284T>C p.L95P | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59749127; called by muse, mutect2
- ZNF629 | c.946A>T p.K316* | Nonsense Mutation (SNP) | VAF 14/220 reads (6%) | catalogued as COSV52699980; called by muse, mutect2
- ZYG11B | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53755671; called by muse, mutect2, varscan2
- RCBTB2 | c.746_759del p.C249Ffs*22 | Frame Shift Del (DEL) | VAF 12/132 reads (9%) | called by mutect2, pindel
- ANO4 | c.2865G>A p.P955= (on ENST00000392977 / NM_001286615.2; = p.P920= on NM_178826.4) | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as rs779812218, COSV54594130; called by muse, mutect2
- BRINP3 | c.1380C>T p.C460= | Silent (SNP) | VAF 9/138 reads (7%) | catalogued as rs1348043617, COSV66526179; called by muse, mutect2
- CNOT6 | c.78A>G p.G26= | Silent (SNP) | VAF 25/314 reads (8%) | catalogued as COSV56163429; called by muse, mutect2
- CSRNP1 | c.1449G>C p.V483= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as COSV56189448; called by muse, mutect2
- CTDSPL | c.177A>C p.P59= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV56203776; called by muse, mutect2
- DENND5B | c.2970G>T p.L990= | Silent (SNP) | VAF 11/205 reads (5%) | catalogued as COSV60906501; called by muse, mutect2
- GPATCH2L | c.1068G>A p.L356= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- LYPD3 | c.141C>T p.N47= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as rs368122649; called by muse, mutect2, varscan2
- OR2V2 | c.567C>T p.A189= | Silent (SNP) | VAF 20/245 reads (8%) | catalogued as COSV60316213; called by muse, mutect2
- PARD3 | c.1053C>T p.P351= | Silent (SNP) | VAF 18/254 reads (7%) | catalogued as COSV60757772; called by muse, mutect2
- PGD | c.465C>T p.T155= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as rs762072878, COSV54622659; called by muse, mutect2
- SH3PXD2A | c.2067C>A p.S689= (on ENST00000369774 / NM_001365079.1; = p.S661= on NM_014631.2) | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs914674678, COSV60119371; called by muse, mutect2
- SH3TC2 | c.1665C>A p.I555= | Silent (SNP) | VAF 17/261 reads (7%) | catalogued as COSV60466469; called by muse, mutect2
- STARD7 | c.462G>A p.R154= | Silent (SNP) | VAF 13/156 reads (8%) | catalogued as COSV61526472; called by muse, mutect2
- SYDE1 | c.330C>A p.I110= | Silent (SNP) | VAF 9/235 reads (4%) | catalogued as COSV100720687; called by muse, mutect2
- UBR4 | c.3411G>A p.E1137= | Silent (SNP) | VAF 12/156 reads (8%) | catalogued as rs866029301, COSV64382485, COSV64396164; called by muse, mutect2
- WDR35 | c.2019T>C p.D673= (on ENST00000345530 / NM_001006657.2; = p.D662= on NM_020779.4) | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV99853318; called by muse, mutect2
- WDR49 | c.1659T>C p.C553= (on ENST00000308378 / NM_001366158.1; = p.C894= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV100393296; called by muse, mutect2
- NDUFV3 | c.170-4883A>G | Intron (SNP) | VAF 6/108 reads (6%) | catalogued as COSV61088276; called by muse, mutect2
